Somatic mutation profile of tumor specimen TCGA-KO-8408-01A (aliquot TCGA-KO-8408-01A-11D-2310-10) from TCGA case TCGA-KO-8408, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 47.4 years (17,299 days).
Specimen TCGA-KO-8408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c9cf308-e088-4eb1-bacc-5047523c9ef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8408-11A (Solid Tissue Normal), aliquot TCGA-KO-8408-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a327a7c6-9436-4542-9f1e-7385ed765de7

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.487A>T p.K163* | Nonsense Mutation (SNP) | VAF 77/105 reads (73%) | catalogued as rs1554898235, COSV64297274; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACLY | c.1461A>G p.G487= | Splice Region (SNP) | VAF 32/43 reads (74%) | catalogued as COSV100709557; called by muse, mutect2, varscan2
- ARSI | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV100155911; called by muse, mutect2, varscan2
- ATP7A | c.2750T>C p.V917A | Missense Mutation (SNP) | VAF 92/107 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100430428; called by muse, mutect2, varscan2
- BMP1 | c.1538A>G p.E513G | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV100109206; called by muse, mutect2, varscan2
- BTBD3 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV99655685; called by muse, mutect2
- CBLB | c.740T>G p.L247W | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912887; called by muse, mutect2, varscan2
- CD5 | c.416C>G p.T139R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100759765; called by muse, mutect2, varscan2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by muse, mutect2, varscan2
- CSF2RB | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1021865587, COSV99453380; called by muse, mutect2
- DCAF10 | c.1387C>G p.H463D | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99647595; called by muse, mutect2, varscan2
- DDI1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs913967126, COSV100160205, COSV56371392; called by muse, mutect2, varscan2
- DIDO1 | c.3746C>G p.A1249G | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759052914, COSV99825074; called by muse, mutect2, varscan2
- DIPK2A | c.862G>T p.V288F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100237123, COSV59857755; called by muse, mutect2, varscan2
- E2F7 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100523362; called by muse, mutect2, varscan2
- EXD1 | c.353G>A p.W118* | Nonsense Mutation (SNP) | VAF 138/327 reads (42%) | catalogued as COSV100153526; called by muse, mutect2, varscan2
- FRAS1 | c.3481C>T p.Q1161* | Nonsense Mutation (SNP) | VAF 32/149 reads (21%) | catalogued as COSV99349243; called by muse, mutect2, varscan2
- HIRA | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99600024; called by muse, mutect2, varscan2
- LCOR | c.3436A>G p.K1146E | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99616672; called by muse, mutect2, varscan2
- MOCS1 | c.1607C>G p.A536G | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99224870; called by muse, mutect2, varscan2
- PPP6R2 | c.128A>T p.K43M | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99323935; called by muse, mutect2, varscan2
- PRDM16 | c.2103G>C p.E701D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99575816; called by muse, mutect2, varscan2
- RBL2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1303305126, COSV100043359, COSV100043376; called by muse, mutect2
- RTN2 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99838779; called by mutect2, varscan2
- RTRAF | c.125T>C p.I42T | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99910806; called by muse, mutect2, varscan2
- RYR1 | c.1632C>G p.D544E | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568448011, COSV100614921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35B4 | c.409A>T p.M137L | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as COSV101043028; called by muse, mutect2, varscan2
- SMPD1 | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100192456; called by muse, mutect2, varscan2
- SPZ1 | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99698091; called by muse, mutect2, varscan2
- SYNM | c.2722A>T p.K908* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as COSV100152519; called by muse, mutect2, varscan2
- TNRC18 | c.7185G>T p.Q2395H | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV100078608; called by muse, mutect2, varscan2
- TOGARAM1 | c.3919G>T p.V1307L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100817880; called by muse, mutect2, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 51/85 reads (60%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- YAP1 | c.1238C>A p.P413Q (on ENST00000282441 / NM_001130145.3; = p.P359Q on NM_006106.5) | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99176050; called by muse, mutect2, varscan2
- ZBTB46 | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99828862; called by muse, mutect2
- ZNF45 | c.1454C>G p.S485* | Nonsense Mutation (SNP) | VAF 33/105 reads (31%) | catalogued as COSV54193910; called by muse, mutect2, varscan2
- ASAH2 | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 22/678 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATRX | c.3370del p.S1124Lfs*6 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- ARID5B | c.429G>A p.L143= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV99689203; called by muse, mutect2
- BPIFB3 | c.1158T>A p.T386= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV100972310; called by muse, mutect2, varscan2
- CELSR3 | c.3828C>T p.T1276= | Silent (SNP) | VAF 75/199 reads (38%) | catalogued as COSV99372870; called by muse, mutect2, varscan2
- CPAMD8 | c.1890C>T p.F630= (on ENST00000651564; = p.F583= on NM_015692.5) | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs776271256, COSV52230579; called by muse, mutect2, varscan2
- DCANP1 | c.297G>A p.S99= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs1328672871, COSV101538223; called by muse, mutect2
- GOLGA6B | c.1110G>A p.Q370= | Silent (SNP) | VAF 14/271 reads (5%) | catalogued as COSV101406902; called by muse, mutect2
- KRT32 | c.384C>T p.I128= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV56787735, COSV99862925; called by muse, mutect2, varscan2
- MYLK2 | c.249C>T p.G83= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs774383057, COSV101044686; ClinVar: likely benign; called by muse, varscan2
- PROX1 | c.1365T>A p.P455= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as COSV99798814; called by muse, mutect2, varscan2
- RIPK2 | c.1404G>A p.L468= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV99609746; called by muse, mutect2, varscan2
- SERTM1 | c.87G>A p.T29= | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as rs202230256, COSV100171264; called by muse, mutect2, varscan2
- STS | c.555G>T p.L185= | Silent (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- TTC7B | c.2289C>T p.H763= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs538193691, COSV100127537; called by muse, mutect2, varscan2
- CLCN5 | c.17-33834A>G | Intron (SNP) | VAF 109/150 reads (73%) | catalogued as rs782355787, COSV101067008; called by muse, mutect2, varscan2
